Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP4-01A (Primary Tumor).

Case #

Patient: Age (years): Gender: Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

ICD-O-3

Melanoma, epithelioid cell
8771/3

Site: Skin, trunk C44.5

g 54/22/14

Gross description:

The material presented – skin from trunk region

Microscopic description:

Skin-fascial flap 10x9x2.5 cm tumor in the center of the mushroom brown size
2.5 cm and a height of 1.2 cm epithelioid cell pigment melanoma without
ulceration, Breslow 15 mm. Clark – V
Stage II A, T4. N0, M0

Final diagnosis: Epithelioid cell melanoma

Confidential

Source: NCI Genomic Data Commons file 64ae21d3-92ea-4a72-971f-bfa8296bb761 (TCGA-BF-AAP4.B25BC3BC-1D2B-4980-8B2F-2C037370087B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).